CCDI case PBCNMZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4b6fff7a-c930-4bf3-99bb-5b7247256509

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Oligoastrocytoma: ICD-O-3 morphology code: 9382/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 18.1 years (6,601 days).

Biospecimens (3 samples)
- Sample 0DW2VO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW2VR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW2W9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
